Gene-level copy-number profile of tumor specimen CDDP-ABLL-TTP1-B from CDDP_EAGLE case CDDP-ABLL, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 68 years.
Specimen CDDP-ABLL-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 241a63c4-10c5-4337-938e-1d21b035ccb4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABLL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,739 have no estimate.
https://portal.gdc.cancer.gov/files/3a27833f-b0ab-4552-a064-38b1e54140ea

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 969; copy number 1: 35,186; copy number 2: 17,424; copy number 3: 4,352; copy number 4: 852; copy number 5: 45; copy number 6: 44; copy number 7: 12.

Homozygous deletions (total copy number 0; autosomes only): 397 genes in 89 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:56,718,789–56,966,140, 4 genes (within-gene range 0–1): FYB2, AL360295.1, C8A, C8B.
- chr1:73,787,370–73,915,340, 2 genes: AL591463.1, RNU4ATAC8P.
- chr4:49,548,564–49,562,149, 5 genes: AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24.
- chr4:190,015,138–190,092,279, 17 genes: RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr5:152,374,998–153,223,543, 4 genes: AC008571.2, NMUR2, AC008571.1, LINC01470.
- chr5:155,397,291–155,845,528, 3 genes: AC010591.1, AC008725.1, RNA5SP199.
- chr6:81,724,722–81,814,157, 4 genes (within-gene range 0–1): AL078599.2, SNORA70, AL078599.1, LINC01526.
- chr7:115,030,564–115,231,355, 4 genes (within-gene range 0–1): LINC01393, LINC01392, RAC1P6, Y_RNA.
- chr7:120,988,697–121,297,442, 4 genes (within-gene range 0–1): CPED1, HMGN1P18, RNA5SP241, RNU6-517P.
- chr8:32,927,913–33,045,445, 4 genes: AC090204.1, MTND1P6, MTND2P32, RANP9.
- chr8:36,277,763–36,321,404, 6 genes: MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2.
- chr9:7,477,045–7,961,224, 6 genes: RPL4P5, PPIAP33, AL354694.1, DMAC1, AL135923.2, AL135923.1.
- chr9:21,695,176–23,438,700, 22 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:117,180,628–118,083,382, 13 genes (within-gene range 0–1): RPL10P3, SNORA70C, RN7SKP128, RN7SKP125, AL445644.1, AL161630.1, RPL35AP22, AL160272.2, TLR4, RNU6-1082P, AL160272.1, AL354754.1, TPT1P9.
- chr10:93,591,687–93,666,010, 2 genes (within-gene range 0–1): RBP4, PDE6C.
- chr11:20,669,551–21,575,686, 7 genes (within-gene range 0–1): NELL1, AC090707.1, RNA5SP336, AC090857.1, AC090857.2, AC099730.1, RNA5SP337.
- chr11:35,210,343–35,214,985, 2 genes (within-gene range 0–1): CD44-AS1, AL133330.1.
- chr11:43,063,637–43,269,393, 3 genes: AC009643.2, AC009643.1, HNRNPKP3.
- chr11:54,706,832–54,725,816, 2 genes: OR4A5, OR4A6P.
- chr11:108,665,069–109,120,986, 8 genes: DDX10, RPS2P39, AP002453.1, CYCSP29, AP003027.1, AP003123.1, RNU6-654P, RNA5SP349.
- chr11:109,355,085–109,638,128, 4 genes: AP003049.2, C11orf87, AP003049.1, AP003102.1.
- chr11:110,577,042–111,305,498, 11 genes (within-gene range 0–1): ARHGAP20, HNRNPA1P60, AP002963.1, RNA5SP350, AP003973.2, LINC02550, AP003973.3, RPS17P15, AP003973.1, C11orf53, COLCA1.
- chr11:111,352,255–111,475,397, 4 genes (within-gene range 0–1): POU2AF1, RNU2-60P, AP002008.3, AP002008.2.
- chr11:112,267,290–113,712,398, 21 genes (within-gene range 0–1): ST13P10, LINC02762, RNU6-44P, LINC02763, RPL23AP62, LINC02764, AP003063.1, AP003100.1, AP000802.1, NCAM1, RNU7-187P, NCAM1-AS1, AP000880.1, TTC12, AP002840.2, ANKK1, AP002840.1, DRD2, MIR4301, TMPRSS5, MTRF1LP1.
- chr11:113,974,881–115,539,384, 26 genes: HTR3A, ZBTB16, AP002755.1, AP002518.2, NNMT, AP002518.1, C11orf71, RBM7, AP002373.1, REXO2, AP002373.2, NXPE2P1, AC020549.3, NXPE1, AC020549.1, NXPE4, AC020549.2, NXPE2, AP003179.1, CADM1, AP000465.1, AP000462.3, AP000462.1, AP000462.2, AP003174.2, AP003174.3.
- chr11:115,920,248–116,610,094, 5 genes: LINC02703, AP000797.2, AP000797.1, LINC02151, AP000770.1.
- chr11:129,375,848–129,612,110, 3 genes: BARX2, RPS27P20, AP003500.1.
- chr11:130,544,643–130,547,429, 2 genes: AP004371.1, BAK1P2.
- chr12:87,746,567–87,750,313, 2 genes: AC079598.4, CYCSP30.
- chr12:118,849,354–118,908,930, 2 genes: AC087863.2, AC087863.1.
- chr13:53,345,211–53,410,880, 2 genes: AL450423.1, ZNF646P1.
- chr14:87,710,419–87,872,291, 2 genes (within-gene range 0–1): AL359237.1, AL136501.1.
- chr15:21,293,653–21,752,710, 25 genes: AC068446.1, RNU6-1235P, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1.
- chr15:21,951,242–21,981,245, 2 genes: MIR5701-3, OR11J6P.
- chr19:27,638,483–27,794,005, 4 genes (within-gene range 0–2): ERVK-28, AC112702.1, LINC00662, AC006504.1.
- chr22:25,434,324–25,520,854, 6 genes: AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2.
- chr22:25,742,144–26,423,193, 12 genes (within-gene range 0–1): MYO18B, AL022329.3, MYO18B-AS1, Z98949.2, RN7SKP169, Z98949.1, LINC02559, AL022337.1, SEZ6L, SEZ6L-AS1, RNA5SP495, Z99714.1.
- chr22:48,139,461–49,657,542, 17 genes: BX284656.2, BX284656.1, MIR3201, Z82249.1, TAFA5, Z84468.1, MIR4535, LINC01310, RPL35P8, Z82202.1, C22orf34, AL008636.1, AL031593.1, MIR3667, Z97192.1, Z97192.2, Z97192.3.
- chr22:49,738,677–50,669,901, 58 genes: RN7SKP252, RPL5P35, BRD1, Z98885.3, Z98885.1, Z98885.2, AL117328.1, Metazoa_SRP, AL117328.2, ZBED4, ALG12, AL671710.1, CRELD2, BX539320.1, PIM3, MIR6821, IL17REL, TTLL8, MLC1, MOV10L1, AL034546.1, PANX2, TRABD, AL022328.3, AL022328.4, SELENOO, AL022328.1, AL022328.2, TUBGCP6, HDAC10, MAPK12, MAPK11, PLXNB2, DENND6B, CR559946.1, CR559946.2, PPP6R2, SBF1, ADM2, MIOX, LMF2, NCAPH2, SCO2, U62317.1, TYMP, ODF3B, U62317.3, KLHDC7B-DT, KLHDC7B, SYCE3, CPT1B, CHKB-CPT1B, CHKB, CHKB-DT, U62317.2, MAPK8IP2, ARSA, Y_RNA.
- chr22:50,735,825–50,801,309, 6 genes: AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 5,305 genes in 171 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–168,376,876, 961 genes, copy number 3 (broad region; genes not listed).
- chr1:194,188,967–248,937,043, 1,143 genes, copy number 3–4 (broad region; genes not listed).
- chr5:58,198–33,522,230, 489 genes, copy number 3–6 (broad region; genes not listed).
- chr5:33,944,623–45,895,970, 187 genes, copy number 3–4 (broad region; genes not listed).
- chr6:2,617,144–3,057,357, 20 genes, copy number 3: LINC02521, LINC01600, MYLK4, WRNIP1, SERPINB1, SERPINB9P1, MIR4645, SERPINB9, AL133351.2, AL133351.1, SERPINB6, LINC01011, NQO2, NQO2-AS1, HTATSF1P2, AL133351.4, AL133351.3, FAM136BP, SERPINB8P1, AL031963.2.
- chr6:3,831,933–5,829,192, 44 genes, copy number 3 (within-gene range 2–3): AL391422.3, AL391422.2, FAM50B, AL590004.3, AL590004.2, AL590004.1, TDGF1P4, GLRX3P2, AL138831.3, AL138831.2, AL138831.1, PRPF4B, FAM217A, C6orf201, ECI2, AL136309.3, ECI2-DT, AL136309.2, AL136309.1, AL162718.1, AL159166.1, RNA5SP202, LINC02533, AL133393.1, AL034376.1, KU-MEL-3, PSMC1P11, CDYL, AL356747.1, CDYL-AS1, AL359643.1, RPP40, LYRM4-AS1, AL359643.2, AL139094.1, PPP1R3G, LYRM4, MIR3691, FARS2, AL121978.1, AL021328.1, HNRNPA1P37, AL022097.1, AL136968.2.
- chr6:7,107,597–8,102,559, 26 genes, copy number 3: RREB1, AL355336.1, Y_RNA, AL589644.1, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1.
- chr6:10,474,500–11,382,348, 28 genes, copy number 3 (within-gene range 3–4): LINC02522, GCNT2, AL139039.3, AL139039.1, AL139039.2, GCNT2P1, AL358777.3, C6orf52, Y_RNA, PAK1IP1, TMEM14C, AL024498.1, TMEM14B, AL024498.2, RNA5SP203, MAK, GCM2, AL357497.1, SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1.
- chr6:17,092,714–18,273,266, 21 genes, copy number 3: AL138740.1, STMND1, AL136305.1, RBM24, AL034372.1, CAP2, RPL7P26, SUMO2P13, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA.
- chr6:19,612,755–23,031,780, 32 genes, copy number 3 (within-gene range 3–4): KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL008627.1, MBOAT1, AL158198.1, AL158198.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL031767.1, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL035401.1.
- chr6:24,365,651–25,057,073, 24 genes, copy number 3: RNU6-391P, MRS2, GPLD1, ALDH5A1, KIAA0319, KRT8P43, TDP2, ACOT13, AL031775.1, C6orf62, AL031775.2, LINC02828, AL133264.1, GMNN, ARMH2, AL512428.1, RIPOR2, MTCO2P33, PPIAP29, AL160400.1, ASS1P1, RN7SL334P, AL133268.3, AL133268.2.
- chr6:25,882,026–26,322,292, 51 genes, copy number 3–4 (within-gene range 2–4): H2AC3P, H2BP5, SLC17A2, TRIM38, U91328.2, U91328.1, U91328.3, H3P26, H1-1, H3C1, H4C1, H4C2, H3C2, H2AC4, H2BC3, H2AC5P, H3C3, H1-2, HFE, H4C3, H1-6, H2BC4, H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3, H4C6, H4C7, H3C7, H2BC9, H3C8, H2AC10P, H2BC10, H4C8, H3C9P.
- chr6:26,596,953–29,636,343, 163 genes, copy number 3–4 (broad region; genes not listed).
- chr6:30,058,899–30,364,280, 23 genes, copy number 3 (within-gene range 2–3): POLR1H, AL669914.4, PPP1R11, RNF39, TRIM31, TRIM31-AS1, AL669914.1, TRIM40, TRIM10, TRIM15, TRIM26, PAIP1P1, HCG17, TRIM26BP, HLA-L, AL662795.2, HCG18, TRIM39, TRIM39-RPP21, RPP21, HLA-N, AL662795.1, UBQLN1P1.
- chr7:37,032–2,529,177, 67 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr7:2,558,972–5,926,550, 60 genes, copy number 3–4 (within-gene range 1–4): IQCE, TTYH3, AMZ1, GNA12, AC006028.1, CARD11, CARD11-AS1, RN7SKP130, AC024028.1, AC073316.1, AC073316.2, SDK1-AS1, SDK1, AC092427.1, AC011284.1, AC017000.1, CYP3A54P, FOXK1, AC092428.1, AP5Z1, MIR4656, AC092610.1, RADIL, Y_RNA, PAPOLB, RPL22P16, MMD2, RNF216P1, AC092032.2, RBAK-RBAKDN, AC092032.3, AC092032.1, SPDYE19P, RBAK, RBAKDN, OR10AH1P, ZNF890P, RNU6-215P, WIPI2, SLC29A4, TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1, FSCN1, RNF216, RNF216-IT1, MIR6874, ZNF815P, RN7SL556P, OCM, CCZ1.
- chr7:5,970,925–8,262,687, 66 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr7:12,211,270–17,346,152, 57 genes, copy number 3–4: TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1, SCIN, AC011891.2, AC011891.3, ARL4A, AC011891.1, AC011287.1, RN7SKP228, RBMX2P4, AC011287.2, AC005019.2, AC005019.1, ETV1, Y_RNA, RPL6P21, DGKB, EEF1A1P26, AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP.
- chr7:20,615,207–23,532,041, 47 genes, copy number 3: ABCB5, AC002486.1, SP8, RPL23P8, LINC01162, RPS26P30, AC080068.1, RN7SL542P, ASS1P11, RNU1-15P, AC005094.1, SP4, MIR1183, DNAH11, CDCA7L, RAPGEF5, RNA5SP227, STEAP1B, EEF1A1P6, AC002480.1, AC002480.2, IL6-AS1, IL6, MTCYBP42, AC073072.1, TOMM7, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A, KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A.
- chr7:27,023,737–27,158,976, 20 genes, copy number 3: TPM3P4, NHP2P2, HOXA1, HOTAIRM1, AC004079.3, AC004079.4, AC004079.2, AC004079.1, AC004079.5, HOXA2, HOXA3, HOXA-AS2, HOXA4, AC004080.6, HOXA-AS3, HOXA5, HOXA6, AC004080.5, HOXA7, AC004080.4.
- chr7:86,216,785–88,756,725, 35 genes, copy number 3–5: SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1.
- chr7:91,638,847–92,971,299, 28 genes, copy number 3–4: AC000058.1, MTERF1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P.
- chr8:51,015,021–52,565,430, 18 genes, copy number 3: AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1.
- chr8:80,265,907–84,142,463, 61 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr8:92,882,984–95,116,455, 62 genes, copy number 3 (broad region; genes not listed).
- chr8:97,772,313–104,256,094, 157 genes, copy number 3–4 (broad region; genes not listed).
- chr11:65,014,160–65,212,006, 27 genes, copy number 3: ARL2, ARL2-SNX15, MIR6879, AP000436.1, SNX15, SAC3D1, NAALADL1, CDCA5, ZFPL1, TMEM262, VPS51, AP003068.1, TM7SF2, ZNHIT2, AP003068.3, AP003068.4, FAU, SYVN1, MRPL49, MIR6751, HIGD1AP10, RNU2-23P, PDCL2P2, SPDYC, PGAM1P8, AP003068.2, CAPN1.
- chr11:76,860,867–78,574,874, 44 genes, copy number 3 (within-gene range 2–3): ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2.
- chr11:85,852,557–86,952,910, 23 genes, copy number 3 (within-gene range 2–3): AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23.
- chr11:89,700,764–89,949,402, 25 genes, copy number 3–4: UBTFL10, AP003122.6, TRIM77, AP003122.4, AP003122.5, UBTFL2, AP003122.2, AP003122.3, AP003122.1, TRIM64DP, AP004833.2, AP004833.3, TRIM49, AP004833.1, TRIM53BP, TRIM51BP, AP005435.1, TRIM64B, AP005435.4, AP005435.2, AP005435.3, MTND1P35, TRIM49D1, TRIM49D2, AP004607.3.
- chr11:90,017,611–91,094,260, 22 genes, copy number 3–5: AP004607.6, TRIM49C, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1, AP000648.2, AP000648.1, AP000648.3, NAALAD2, AP000648.4, CHORDC1, AP002364.1, DISC1FP1, TUBAP2, MIR4490, AP002782.1, MIR1261, AP001002.3, AP001002.1, AP001002.2.
- chr14:34,485,979–51,979,342, 277 genes, copy number 3–7 (within-gene range 2–7) (broad region; genes not listed).
- chr14:51,989,514–53,883,740, 31 genes, copy number 3 (within-gene range 2–3): RTRAF, NID2, LINC02319, COX5AP2, AL118557.1, PTGDR, AL365475.1, PTGER2, TXNDC16, GPR137C, ERO1A, AL133453.1, PSMC6, STYX, GNPNAT1, AL139317.3, AL139317.5, AL139317.1, AL139317.2, FERMT2, AL139317.4, AL352979.4, AL352979.1, AL352979.3, DDHD1, AL352979.2, AL356020.1, AL365295.1, AL365295.2, AL163953.1, RPS3AP46.
- chr14:54,396,849–55,796,731, 38 genes, copy number 3: CDKN3, CNIH1, AL359792.1, GMFB, CGRRF1, SAMD4A, AL133444.1, GCH1, RNU6ATAC9P, MIR4308, FDPSP3, WDHD1, RPSAP13, SOCS4, MAPK1IP1L, LGALS3, DLGAP5, AL139316.1, AL158801.4, COX5AP1, AL158801.2, FBXO34, AL158801.1, Metazoa_SRP, CHMP4BP1, AL158801.3, ATG14, HMGN1P1, TBPL2, RPL21P6, KTN1-AS1, RPL7AP4, ABI1P1, KTN1, Y_RNA, AL355773.1, RPL13AP3, LINC00520.
- chr14:56,117,316–60,572,311, 86 genes, copy number 3 (broad region; genes not listed).
- chr18:20,946,906–24,162,211, 72 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr18:25,953,216–26,657,401, 17 genes, copy number 3–4 (within-gene range 2–4): AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P.
- chr18:30,713,275–33,441,101, 58 genes, copy number 3–4: AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC025887.1, KLHL14, AC012123.1, AC012123.2, AC090371.2, CCDC178, AC090371.1.
- chr18:34,493,290–35,497,979, 22 genes, copy number 3 (within-gene range 2–3): DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5.
- chr19:36,496,916–36,998,700, 20 genes, copy number 3: CTBP2P7, ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568.

Autosomal genes at a single copy (total copy number 1): 32,902. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
